Gene-level copy-number profile of tumor specimen TCGA-66-2756-01A from TCGA case TCGA-66-2756, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 68.3 years (24,929 days).
Specimen TCGA-66-2756-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.682c20a4-f1d6-4fb9-aa2d-5835d3247228.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2756-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/53587cf9-a92a-423f-b8ae-20508b507ef7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 101; copy number 2: 14,650; copy number 3: 18,898; copy number 4: 12,413; copy number 5: 6,775; copy number 6: 2,603; copy number 7: 525; copy number 8: 1,688; copy number 9: 367; copy number 10: 689; copy number 11: 621; copy number 12: 214; copy number 13: 141; copy number 14: 92; copy number 19: 2; copy number 30: 8; copy number 40: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2756-01A-01D-0844-01): tumor purity 0.71, ploidy 3.73, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,372 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,560,709–39,944,998, 22 genes, copy number 10: PABPC4, PABPC4-AS1, SNORA55, HEYL, AL035404.2, NT5C1A, HPCAL4, PPIE, AL035404.1, RNU7-121P, BMP8B, OXCT2, BMP8B-AS1, AL033527.2, AL033527.1, AL033527.3, LINC02811, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA.
- chr1:72,283,170–72,753,772, 1 gene, copy number 8 (within-gene range 3–8): AL513166.1.
- chr1:72,636,547–78,750,659, 93 genes, copy number 8 (broad region; genes not listed).
- chr2:13,537,673–23,199,056, 118 genes, copy number 7–8 (broad region; genes not listed).
- chr2:28,782,517–29,955,405, 19 genes, copy number 7 (within-gene range 3–7): SPDYA, AC097724.1, TRMT61B, WDR43, SNORD92, SNORD53, Y_RNA, SNORD53B, TOGARAM2, Y_RNA, PCARE, AC105398.1, CLIP4, ALK, AC074096.1, RN7SL516P, AC106870.3, AC106870.2, AC106870.1.
- chr2:30,077,093–30,078,272, 1 gene, copy number 7: AC016907.1.
- chr2:32,357,028–32,946,149, 13 genes, copy number 8: BIRC6, BIRC6-AS1, AL133243.2, AL133243.3, MIR558, AL133243.1, BIRC6-AS2, AL133243.4, TTC27, MIR4765, LINC00486, LINC00486, Y_RNA.
- chr2:39,436,530–40,255,209, 5 genes, copy number 9 (within-gene range 3–9): MAP4K3-DT, TMEM178A, THUMPD2, SLC8A1-AS1, AC007253.1.
- chr2:42,333,546–53,970,993, 180 genes, copy number 7–10 (within-gene range 4–10) (broad region; genes not listed).
- chr2:55,172,547–55,232,563, 2 genes, copy number 7 (within-gene range 5–7): CLHC1, AC012358.1.
- chr2:78,597,911–80,648,861, 18 genes, copy number 10 (within-gene range 3–10): AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080.
- chr2:95,207,535–99,154,964, 124 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr2:99,141,707–99,199,561, 5 genes, copy number 8 (within-gene range 3–8): C2orf15, LIPT1, AC092587.1, MITD1, MRPL30.
- chr2:113,157,325–124,915,287, 135 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr2:134,119,983–134,454,621, 1 gene, copy number 9 (within-gene range 4–9): MGAT5.
- chr2:134,319,654–150,356,460, 163 genes, copy number 8–11 (within-gene range 4–11) (broad region; genes not listed).
- chr2:152,850,653–153,208,163, 5 genes, copy number 11: AC009969.1, UBQLN4P2, ATP5PBP4, AC011901.1, AC079150.1.
- chr2:155,263,458–166,611,482, 145 genes, copy number 8–9 (broad region; genes not listed).
- chr2:183,253,652–183,495,501, 1 gene, copy number 9 (within-gene range 3–9): AC021851.2.
- chr2:183,607,442–184,187,573, 5 genes, copy number 9 (within-gene range 3–9): CACYBPP2, AC093639.3, AC093639.1, AC093639.2, AC096555.1.
- chr2:217,978,707–218,453,295, 23 genes, copy number 9: TNS1-AS1, RUFY4, CXCR2P1, CXCR2, CXCR1, HMGB1P9, ARPC2, AC021016.1, GPBAR1, AAMP, PNKD, TMBIM1, MIR6513, CATIP-AS2, MIR6810, RPL19P5, CATIP, CATIP-AS1, SLC11A1, CTDSP1, AC021016.2, MIR26B, VIL1.
- chr5:58,198–56,606,232, 825 genes, copy number 8–14 (broad region; genes not listed).
- chr5:136,975,298–137,810,751, 7 genes, copy number 11 (within-gene range 2–11): SPOCK1, KLHL3, MIR874, HNRNPA0, AC106791.3, AC106791.2, NPY6R.
- chr7:122,318,411–122,886,759, 1 gene, copy number 11 (within-gene range 3–11): CADPS2.
- chr7:122,676,580–122,702,922, 4 genes, copy number 11: AC006463.1, RPS26P31, RNF133, RNF148.
- chr7:124,822,386–125,482,966, 6 genes, copy number 11 (within-gene range 3–11): POT1, POT1-AS1, EEF1GP1, LINC02830, AC019155.1, AC019155.2.
- chr7:139,561,570–151,877,125, 382 genes, copy number 8–19 (within-gene range 4–19) (broad region; genes not listed).
- chr8:31,827,238–31,840,709, 1 gene, copy number 10: AC068931.1.
- chr8:33,604,856–34,039,104, 1 gene, copy number 9 (within-gene range 2–9): AF279873.3.
- chr8:33,715,784–34,874,633, 11 genes, copy number 9: RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1.
- chr8:37,405,439–88,887,573, 803 genes, copy number 7–14 (within-gene range 4–14) (broad region; genes not listed).
- chr8:88,808,318–106,060,524, 319 genes, copy number 8–10 (within-gene range 5–10) (broad region; genes not listed).
- chr8:106,215,763–145,066,685, 578 genes, copy number 8–10 (broad region; genes not listed).
- chr9:26,642,697–35,049,563, 178 genes, copy number 7–40 (broad region; genes not listed).
- chr22:17,980,868–21,192,156, 177 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 24. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
